Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7238, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7238-01A (Primary Tumor).

[page 1 of 3]
Collected: [REDACTED]

Received: [REDACTED]

Case type: Surgical Case

Accession: [REDACTED]

DIAGNOSIS

(A) LEFT SELECTIVE NECK DISSECTION, LEVEL I:

Six lymph nodes, no tumor present (0/6).

Salivary gland, no tumor present.

(B) LEFT SELECTIVE NECK DISSECTION, LEVEL II:

Ten lymph nodes, no tumor present (0/10).

(C) LEFT SELECTIVE NECK DISSECTION, LEVEL III:

Eighteen lymph nodes, no tumor present (0/18).

(D) LEFT SELECTIVE NECK DISSECTION, LEVEL IV:

Nine lymph nodes, no tumor present (0/9).

(E) LEFT PARTIAL GLOSSECTOMY:

INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated

Tumor Features:

Gross: Ulcerating

Size: 3.4 cm in largest dimension

Invasion: Present, depth 1.4 cm

Tumor Border: Infiltrative with thick cords > 4 cells

Perineural Invasion: Present, Moderate

Vascular Invasion: Absent

Lymphocyte Infiltration: Moderate

Mucosal Margin: (en-face) Negative for invasive carcinoma

Deep Margin: (radial) Negative for invasive carcinoma

Dysplasia at Margin: Present, Severe dysplasia at Posterolateral margin(s).

(F) POSTERIOR GINGIVAL MARGIN:

Squamous mucosa, no tumor present.

(G) POSTERIOR PHARYNGEAL MARGIN:

Squamous mucosa, no tumor present.

Entire report and diagnosis completed by [REDACTED]

GROSS DESCRIPTION

(A) LEFT SELECTIVE NECK DISSECTION LEVEL I - Received is a fragment of fatty tissue with attached glandular tissue. Glandular tissue measures 3.5 x 3.0 x 1.5 cm. Fatty tissue measures 6.5 x 3.0 x 1.5 cm. Dissection of the fatty tissue reveals six possible lymph nodes ranging from 0.5 x 0.5 cm up to 1.1 x 1.0 cm. The cut surface of the glandular tissue is unremarkable. Entire nodes and representative sections of the glandular tissue are submitted.

SECTION CODE: A1, four possible lymph nodes; A2, one sectioned possible lymph node; A3, one sectioned possible lymph node; A4, representative sections of the glandular tissue. [REDACTED]

[page 2 of 3]
(B) LEFT SELECTIVE NECK DISSECTION, LEVEL II - Received are fibrofatty fragments of soft tissue (3.5 x 2.5 x 1.0 cm). Specimen is palpated to reveal ten possible lymph nodes (ranging from 0.3 x 0.2 x 0.2 cm up to 1.5 x 1.0 x 0.6 cm). Specimen nodes are entirely submitted.

SECTION CODE: B1, four possible lymph nodes; B2, two possible lymph nodes; B3, two possible lymph nodes; B4, one possible lymph node bisected; B5, one possible lymph node.

(C) LEFT SELECTIVE NECK DISSECTION, LEVEL III - Received fibrofatty fragments of soft tissue (4.0 x 2.0 x 2.0 cm in aggregate). The specimen is palpated and serially sectioned revealing ten possible lymph nodes (ranging from 0.5 x 0.3 x 0.2 cm up to 1.7 x 0.8 x 0.7 cm). The specimen nodes are entirely submitted.

SECTION CODE: C1, four possible lymph nodes; C2, three possible lymph nodes; C3, two possible lymph nodes; C4, largest possible lymph node, bisected.

(D) LEFT SELECTIVE NECK DISSECTION, LEVEL IV - An irregular fragment of fat (2.5 x 2.0 x 0.9 cm).

SECTION CODE: D1, four possible lymph nodes; D2, five possible lymph nodes.

(E) LEFT PARTIAL GLOSSECTOMY, STITCH-ANTERIOR, CHECK ALL MARGINS PERIPHERAL AND DEEP - Received is a left partial glossectomy specimen (8.0 x 3.0 x 2.5 cm) which has been sliced from anterior (slice 1) to posterior (slice 11).

Within slices 6-8 there is a scirrhous, white tumor (3.4 x 2.0 cm, 1.4 cm depth of gross invasion) which approaches the nearest lateral gingival margin to 0.7 cm. The tumor approaches the nearest medial margin to 1.0 cm and the nearest deep margin to 2.2 cm. No other lesions are identified. The margins are shaved and submitted for frozen section. Perpendicular section through slices 6-8 in relationship to lateral margin are submitted for frozen section.

INK CODE: Black-deep margin; blue-medial margin; orange-lateral margin.

SECTION CODE: E1-E7, mucosal shaved margins, en face (please see diaphragm); E8-E10, perpendicular sections through slices 6, 7, and 8, respectively; E11, slice 5 (anterior to tumor); E12, slice 6, perpendicular section; E13, E14, slice 7, bisected, perpendicular sections; E15-E17, slice 8, trisected, perpendicular sections.

*FS/DX: SEVERE DYSPLASIA, NO TUMOR PRESENT.

SQUAMOUS CELL CARCINOMA.

(F) POSTERIOR GINGIVAL MARGIN, STITCH ANTERIOR, INK AT TRUE MARGIN - A 4.0 x 1.0 x 1.0 cm portion of pink-tan mucosal lined tissue. The true margin is re-inked blue.

INK CODE: Blue-true margin.

SECTION CODE: F1-F5, posterior gingival margin, serially sectioned and submitted entirely from anterior to posterior for frozen section.

*FS/DX: NO TUMOR PRESENT.

(G) POSTERIOR PHARYNGEAL MARGIN, STITCH ANTERIOR, INK TRUE MARGIN - A longitudinal piece of mucosa with underlying soft tissue (3.5 cm in length and 0.5 cm in average diameter).

INK CODE: Blue - anterior true margin; yellow posterior true margin.

SECTION CODE: The specimen is submitted entirely in G, for frozen section diagnosis.

*FS/DX: NO TUMOR PRESENT.

CLINICAL HISTORY

Left oral squamous cell carcinoma.

SNOMED CODES

M-80703, M-43000, M-Y4030,

[page 3 of 3]
Released by: [Redacted]

Page 3 of 3	
Surgical Pathology Report	
File under: Pathology	

Source: NCI Genomic Data Commons file 36c04cf2-fa1c-4455-b996-36daed0f5a9a (TCGA-CV-7238.5599312B-BCB5-4CF5-A201-BFC136CE6E46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).